Gene-level copy-number profile of tumor specimen TCGA-AN-A0FT-01A from TCGA case TCGA-AN-A0FT, project TCGA-BRCA (Breast Invasive Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage IIB; Age at diagnosis: 63.8 years (23,300 days).
Specimen TCGA-AN-A0FT-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-BRCA.8f41eb88-b15f-4b04-934a-0a110a544fbc.absolute_liftover.gene_level_copy_number.v36.tsv, workflow ABSOLUTE segment calls lifted over to GRCh38 (Affymetrix SNP 6.0); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 6,651 have no estimate.
https://portal.gdc.cancer.gov/files/7d949cac-5303-4aeb-94a8-3e236de2b02c

Most common (modal) total copy number across autosomal genes: 6 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 10; copy number 2: 393; copy number 3: 3,714; copy number 4: 14,015; copy number 5: 4,859; copy number 6: 16,609; copy number 7: 14,372.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-AN-A0FT-01A-11D-A036-01): tumor purity 0.62, ploidy 5.83, whole-genome doublings 2.

Homozygous deletions (total copy number 0; autosomes only): 10 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr22:48,044,710–48,489,324, 10 genes: FP325330.1, FP325330.2, BX284656.2, BX284656.1, AL008720.1, MIR3201, AL008720.2, Z72006.1, Z82249.1, Z84468.2.

Amplified relative to the modal value (total copy number ≥ 13, i.e. more than twice the modal value of 6; autosomes only): none.

Autosomal genes at a single copy (total copy number 1): 0. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
